Somatic mutation profile of tumor specimen TARGET-30-PAPRPR-01A (aliquot TARGET-30-PAPRPR-01A-01D) from TARGET case TARGET-30-PAPRPR, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 1.7 years (614 days).
Specimen TARGET-30-PAPRPR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c57cc14c-b7b2-41cb-9f14-c070e8b5ffe2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPRPR-10A (Blood Derived Normal), aliquot TARGET-30-PAPRPR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0226272e-8cd9-4016-930d-5ef6d9fa335a

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AJUBA | c.1058A>C p.Q353P | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV52984413; called by muse, mutect2, varscan2
- CCDC170 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53336597; called by muse, mutect2, varscan2
- CCT6A | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV51904450; called by muse, mutect2, varscan2
- GJA1 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV56996970, COSV56999820; called by muse, mutect2, varscan2
- ILF2 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV62626774, COSV62627741; called by muse, mutect2, varscan2
- SIN3B | c.1513A>T p.I505F | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56131135; called by muse, mutect2, varscan2
- TRO | c.3521G>A p.S1174N | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV99436992; called by muse, mutect2, varscan2
- TRO | c.3522C>A p.S1174R | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARMC4 | c.1026C>T p.D342= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV53462596; called by muse, mutect2, varscan2
- ELOA3 | c.951C>T p.N317= | Silent (SNP) | VAF 38/886 reads (4%) | catalogued as rs768515776, COSV55296578; called by muse, mutect2
- RPL23AP82 | n.504C>A | RNA (SNP) | VAF 31/101 reads (31%) | called by muse, mutect2, varscan2
